Somatic mutation profile of tumor specimen C3L-04031-05 (aliquot CPT0231560006) from CPTAC case C3L-04031, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 73.3 years (26,760 days).
Specimen C3L-04031-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0b21dad6-ee3a-4686-8810-b484356481df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04031-31 (Blood Derived Normal), aliquot CPT0231680002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52a13eb7-1004-4c95-8b28-399c68ba2174

The open-access MAF lists 69 somatic variants for this specimen: 41 protein-altering or splice-affecting, 19 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 19, Intron 5, Frame Shift Del 2, RNA 2, Nonsense Mutation 1, Splice Site 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.695T>C p.I232T | Missense Mutation (SNP) | VAF 152/389 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs587781589, CM103212, COSV52661257, COSV52760307, COSV52829354; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ACOX2 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 19/340 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs200714050; called by muse, mutect2
- ADGRF4 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs780412651, COSV51949699; called by muse, mutect2, varscan2
- CCDC9B | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.88); PolyPhen benign (0.053); catalogued as rs953586783; called by mutect2, varscan2
- DZIP3 | c.3168C>G p.F1056L | Missense Mutation (SNP) | VAF 10/290 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as rs1373511077, COSV64311790; called by muse, mutect2
- HEATR5A | c.4316C>T p.S1439L | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs761348027; called by muse, mutect2
- IGKV1-9 | c.332A>T p.Q111L | Missense Mutation (SNP) | VAF 116/524 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs763607532; called by muse, mutect2, varscan2
- INPP5E | c.608C>G p.S203C | Missense Mutation (SNP) | VAF 26/549 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs1214397440, COSV51525915; called by muse, mutect2
- KCNC4 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 55/255 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1193440653; called by muse, mutect2, varscan2
- MID1 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 26/262 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM070997, COSV100452720; called by muse, mutect2, varscan2
- MYH7 | c.5268G>T p.K1756N | Missense Mutation (SNP) | VAF 26/649 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100806251; called by muse, mutect2
- OR6N1 | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs138590619; called by muse, mutect2
- PTK7 | c.505del p.L169Ffs*17 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | catalogued as rs35848762; called by mutect2, pindel, varscan2
- PTPRC | c.3520C>T p.Q1174* | Nonsense Mutation (SNP) | VAF 13/358 reads (4%) | catalogued as COSV100722147; called by muse, mutect2
- RNF175 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 24/338 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs752702677; called by muse, mutect2
- SEMA4C | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs539849379, COSV59691127; called by muse, mutect2, varscan2
- SLC16A12 | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 67/342 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs1332703009; called by muse, mutect2, varscan2
- SPATA5 | c.2275G>A p.G759R | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1214027110, COSV56771114; called by muse, mutect2, varscan2
- TTN | c.52657C>T p.H17553Y (on ENST00000591111; = p.H10129Y on NM_003319.4) | Missense Mutation (SNP) | VAF 89/378 reads (24%) | PolyPhen benign (0.119); catalogued as rs904491441; called by muse, mutect2, varscan2
- ZNF829 | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV66987024; called by muse, mutect2, varscan2
- ACBD6 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 13/368 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2
- ADAMTSL4 | c.2111G>C p.S704T | Missense Mutation (SNP) | VAF 72/355 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- API5 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.272); called by muse, mutect2
- B4GALNT4 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.43); called by muse, mutect2
- CNGA4 | c.1480G>C p.E494Q | Missense Mutation (SNP) | VAF 20/355 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.141); called by muse, mutect2
- CUBN | c.452A>G p.H151R | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- FSD2 | c.170G>C p.G57A | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2
- GOLGA5 | c.1892G>C p.G631A | Missense Mutation (SNP) | VAF 12/345 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- KREMEN1 | c.206T>G p.L69R (on ENST00000407188; = p.L71R on NM_032045.5) | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MAGED2 | c.1329G>T p.W443C | Missense Mutation (SNP) | VAF 34/352 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAML1 | c.908C>G p.S303C | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MSH3 | c.470del p.Q157Rfs*76 | Frame Shift Del (DEL) | VAF 33/300 reads (11%) | called by mutect2, pindel, varscan2
- PAPPA2 | c.4438T>C p.S1480P | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDHB1 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PPL | c.1709G>T p.G570V | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SAGE1 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.771); called by muse, mutect2
- SETD2 | c.6109_6109+9del p.X2037_splice | Splice Site (DEL) | VAF 20/116 reads (17%) | called by mutect2, pindel, varscan2
- SLC4A2 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.051); called by muse, mutect2
- TP63 | c.732C>G p.C244W | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSC1 | c.179T>A p.I60N | Missense Mutation (SNP) | VAF 145/519 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- USP11 | c.7G>A p.V3I | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by muse, mutect2
- ASH1L | c.2427A>G p.L809= | Silent (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- AZI2 | c.747C>G p.T249= | Silent (SNP) | VAF 69/333 reads (21%) | called by muse, mutect2, varscan2
- FAM160A1 | c.2721T>A p.S907= | Silent (SNP) | VAF 21/160 reads (13%) | called by muse, mutect2, varscan2
- FAM200A | c.939A>G p.V313= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as rs1335725501; called by muse, mutect2, varscan2
- FN1 | c.5100C>T p.V1700= | Silent (SNP) | VAF 14/444 reads (3%) | called by muse, mutect2
- GARRE1 | c.174C>T p.T58= | Silent (SNP) | VAF 46/170 reads (27%) | catalogued as rs780342636; called by muse, mutect2, varscan2
- KCNH6 | c.381C>T p.L127= | Silent (SNP) | VAF 14/308 reads (5%) | called by muse, mutect2
- KEAP1 | c.867G>A p.E289= | Silent (SNP) | VAF 19/618 reads (3%) | called by muse, mutect2
- LRRC32 | c.1302C>T p.S434= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs751596693, COSV52634617; called by muse, mutect2, varscan2
- NHLH2 | c.18C>T p.D6= | Silent (SNP) | VAF 107/566 reads (19%) | called by muse, mutect2, varscan2
- NLRC4 | c.1008G>A p.K336= | Silent (SNP) | VAF 21/280 reads (8%) | called by muse, mutect2
- PRR14 | c.1308G>A p.E436= | Silent (SNP) | VAF 16/254 reads (6%) | catalogued as rs755852798; called by muse, mutect2
- RABL6 | c.1224C>G p.T408= | Silent (SNP) | VAF 21/261 reads (8%) | called by muse, mutect2
- REN | c.1206C>T p.F402= | Silent (SNP) | VAF 27/640 reads (4%) | catalogued as rs777391884, COSV65817392; called by muse, mutect2
- ST3GAL3 | c.771C>T p.I257= (on ENST00000361392 / NM_174964.4; = p.I242= on NM_006279.5) | Silent (SNP) | VAF 24/471 reads (5%) | catalogued as rs148477698; called by muse, mutect2
- TBXA2R | c.318C>T p.R106= | Silent (SNP) | VAF 96/684 reads (14%) | called by muse, mutect2, varscan2
- TMEM17 | c.328T>C p.L110= | Silent (SNP) | VAF 28/102 reads (27%) | called by muse, mutect2
- UTP14A | c.1461C>T p.V487= | Silent (SNP) | VAF 14/280 reads (5%) | catalogued as COSV64088084; called by muse, mutect2
- ZNF536 | c.144C>T p.P48= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as rs748565785, COSV100835936; called by muse, mutect2
- ADAM6 | n.736C>T | RNA (SNP) | VAF 29/232 reads (13%) | catalogued as rs1277345381; called by muse, mutect2, varscan2
- ATP6V0E1 | chr5:173020846 T>G | 3'Flank (SNP) | VAF 112/428 reads (26%) | catalogued as rs1193896010; called by muse, mutect2, varscan2
- CXCL8 | c.201-23G>A | Intron (SNP) | VAF 59/170 reads (35%) | called by muse, mutect2, varscan2
- ERICH1 | c.977-11820G>A | Intron (SNP) | VAF 11/138 reads (8%) | called by muse, mutect2
- GLG1 | c.2053-234C>T | Intron (SNP) | VAF 13/159 reads (8%) | called by muse, mutect2
- GRM6 | c.2125-250G>A | Intron (SNP) | VAF 60/319 reads (19%) | catalogued as rs753735741; called by muse, mutect2, varscan2
- LINC00482 | n.819G>A | RNA (SNP) | VAF 124/285 reads (44%) | catalogued as rs113085388; called by muse, mutect2, varscan2
- SLC39A8 | c.*32C>T | 3'UTR (SNP) | VAF 21/129 reads (16%) | catalogued as rs917960793; called by muse, mutect2, varscan2
- XPNPEP2 | c.490+26T>A | Intron (SNP) | VAF 42/215 reads (20%) | called by muse, mutect2, varscan2
